Somatic mutation profile of tumor specimen MMRF_2281_1_BM_CD138pos (aliquot MMRF_2281_1_BM_CD138pos_T1_KHS5U_L09554) from MMRF case MMRF_2281, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 51.8 years (18,936 days).
Specimen MMRF_2281_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8eaddbcb-fc05-43f5-a7a5-43d2551a1375.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2281_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2281_1_PB_Whole_C2_KHS5U_L09555; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/180e9aad-eb2f-4e02-b026-18bd9cfcc6e0

The open-access MAF lists 110 somatic variants for this specimen: 49 protein-altering or splice-affecting, 19 silent, 42 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 40, 3'UTR 29, Silent 19, Intron 6, Frame Shift Del 3, Splice Site 3, Nonsense Mutation 2, 3'Flank 2, RNA 2, 5'UTR 2, Splice Region 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACP7 | c.1133C>T p.T378M | Missense Mutation (SNP) | VAF 116/168 reads (69%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as rs752863007, COSV58700196; called by muse, mutect2, varscan2
- C3 | c.2852G>A p.R951H | Missense Mutation (SNP) | VAF 128/198 reads (65%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs145374290, CM161606, COSV99837412; called by muse, mutect2, varscan2
- COL21A1 | c.1220G>A p.R407Q | Missense Mutation (SNP) | VAF 82/157 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1371785735; called by muse, mutect2, varscan2
- DIS3 | c.1631T>C p.L544P | Missense Mutation (SNP) | VAF 24/26 reads (92%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs753101594; called by muse, mutect2, varscan2
- DSP | c.4471G>A p.D1491N | Missense Mutation (SNP) | VAF 95/219 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs768402359; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GMCL1 | c.785G>A p.G262D | Missense Mutation (SNP) | VAF 29/60 reads (48%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV99247951; called by muse, mutect2, varscan2
- HUNK | c.1816G>A p.G606R | Missense Mutation (SNP) | VAF 105/241 reads (44%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.007); catalogued as rs539652834; called by muse, mutect2, varscan2
- HYDIN | c.487C>T p.R163* | Nonsense Mutation (SNP) | VAF 36/95 reads (38%) | catalogued as COSV55489951; called by muse, mutect2, varscan2
- LTBP1 | c.4522C>T p.R1508* (on ENST00000404816 / NM_206943.4; = p.R1182* on NM_000627.4) | Nonsense Mutation (SNP) | VAF 16/174 reads (9%) | catalogued as rs1193082737, COSV55386724; called by muse, mutect2
- MAF | c.1043A>G p.Y348C | Missense Mutation (SNP) | VAF 123/247 reads (50%) | SIFT tolerated (0.15); PolyPhen benign (0.242); catalogued as rs778650605; called by muse, varscan2
- MAF | c.131G>C p.S44T | Missense Mutation (SNP) | VAF 27/56 reads (48%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.584); catalogued as COSV58153826; called by muse, mutect2, varscan2
- NAP1L2 | c.944A>T p.Y315F | Missense Mutation (SNP) | VAF 52/55 reads (95%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.677); catalogued as rs749891173; called by muse, mutect2, varscan2
- NFKBIA | c.336+8G>A | Splice Region (SNP) | VAF 59/128 reads (46%) | catalogued as rs772605839; called by muse, mutect2, varscan2
- OR13D1 | c.132C>A p.F44L | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); catalogued as rs759739126, COSV59513579, COSV59513660; called by muse, mutect2, varscan2
- PPRC1 | c.2728C>G p.L910V | Missense Mutation (SNP) | VAF 139/294 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.006); catalogued as rs1418550719; called by muse, mutect2, varscan2
- PTPN21 | c.2198G>A p.R733H | Missense Mutation (SNP) | VAF 37/101 reads (37%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as rs1461721444, COSV100161558, COSV100161857; called by muse, mutect2, varscan2
- RANBP6 | c.8C>T p.A3V | Missense Mutation (SNP) | VAF 61/163 reads (37%) | SIFT tolerated, low confidence (0.66); PolyPhen possibly damaging (0.739); catalogued as rs777633234; called by muse, mutect2, varscan2
- SLC17A8 | c.224G>A p.R75H | Missense Mutation (SNP) | VAF 56/106 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs559227009, COSV60122562; called by muse, mutect2, varscan2
- TMC6 | c.715G>A p.G239S | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as rs767247094; called by muse, varscan2
- ULBP1 | c.347T>C p.I116T | Missense Mutation (SNP) | VAF 26/126 reads (21%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs754671137; called by muse, mutect2, varscan2
- ABCA8 | c.51C>G p.C17W | Missense Mutation (SNP) | VAF 40/91 reads (44%) | SIFT tolerated (0.66); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- ATRIP | c.1658C>T p.T553I | Missense Mutation (SNP) | VAF 40/84 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.106); called by muse, mutect2, varscan2
- BRCA1 | c.1060A>T p.N354Y | Missense Mutation (SNP) | VAF 124/290 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- C1orf94 | c.1551G>T p.M517I (on ENST00000488417 / NM_001134734.2; = p.M327I on NM_032884.5) | Missense Mutation (SNP) | VAF 13/113 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- CACNA1S | c.5135-2A>G p.X1712_splice | Splice Site (SNP) | VAF 6/75 reads (8%) | called by muse, mutect2
- CD46 | c.947-2A>G p.X316_splice | Splice Site (SNP) | VAF 7/67 reads (10%) | called by muse, mutect2
- COX6A2 | c.274A>T p.T92S | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT tolerated (0.2); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- DGKH | c.322G>T p.V108F | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- DLL4 | c.175C>T p.R59C | Missense Mutation (SNP) | VAF 31/220 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- DPY19L2 | c.86G>A p.R29Q | Missense Mutation (SNP) | VAF 20/108 reads (19%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GPRASP2 | c.2335A>G p.I779V | Missense Mutation (SNP) | VAF 41/43 reads (95%) | SIFT tolerated (0.46); PolyPhen benign (0.416); called by muse, mutect2, varscan2
- IGHV3-21 | c.310A>G p.S104G | Missense Mutation (SNP) | VAF 36/55 reads (65%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.166); called by muse, varscan2
- JTB | c.15_28del p.G6Pfs*55 | Frame Shift Del (DEL) | VAF 273/412 reads (66%) | called by mutect2, pindel, varscan2
- LCE2C | c.82T>C p.C28R | Missense Mutation (SNP) | VAF 378/569 reads (66%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.918); called by muse, mutect2, varscan2
- LY6H | c.-61-2dup | Splice Site (INS) | VAF 17/55 reads (31%) | called by mutect2, pindel, varscan2
- MAF | c.823A>C p.N275H | Missense Mutation (SNP) | VAF 57/128 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MAF | c.296A>C p.Q99P | Missense Mutation (SNP) | VAF 41/102 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.481); called by muse, mutect2, varscan2
- NFE2L3 | c.2031A>C p.K677N | Missense Mutation (SNP) | VAF 71/205 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- OTUD4 | c.908del p.A303Efs*43 (on ENST00000447906 / NM_001366057.1; = p.A238Efs*43 on NM_001102653.1) | Frame Shift Del (DEL) | VAF 13/31 reads (42%) | called by mutect2, pindel*
- PRSS35 | c.511G>T p.V171F | Missense Mutation (SNP) | VAF 73/143 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); called by muse, mutect2, varscan2
- RNF8 | c.1048_1061del p.L350Kfs*8 | Frame Shift Del (DEL) | VAF 88/187 reads (47%) | called by mutect2, pindel, varscan2
- SALL3 | c.2747G>A p.R916H | Missense Mutation (SNP) | VAF 36/65 reads (55%) | SIFT tolerated (0.5); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SCART1 | c.2846A>G p.Y949C | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- SDK1 | c.527G>C p.G176A | Missense Mutation (SNP) | VAF 52/185 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SDK1 | c.5456A>T p.N1819I | Missense Mutation (SNP) | VAF 128/210 reads (61%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SERTAD4 | c.1046G>A p.C349Y | Missense Mutation (SNP) | VAF 56/385 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.88); called by muse, mutect2, varscan2
- TCF7L2 | c.1436C>G p.P479R (on ENST00000355995 / NM_001367943.1; = p.P456R on NM_030756.5) | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- TCHH | c.5057G>T p.R1686L | Missense Mutation (SNP) | VAF 26/230 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- TMEM168 | c.1492T>C p.Y498H | Missense Mutation (SNP) | VAF 17/138 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- AP3M2 | c.237C>T p.V79= | Silent (SNP) | VAF 44/106 reads (42%) | called by muse, mutect2, varscan2
- CAPZA3 | c.207A>T p.P69= | Silent (SNP) | VAF 99/245 reads (40%) | called by muse, mutect2, varscan2
- COL5A2 | c.1086T>A p.P362= | Silent (SNP) | VAF 31/82 reads (38%) | called by muse, mutect2, varscan2
- COL6A3 | c.3750C>T p.Y1250= | Silent (SNP) | VAF 93/219 reads (42%) | catalogued as rs763648429, COSV55102627; ClinVar: likely benign; called by muse, mutect2, varscan2
- CSMD1 | c.3018T>C p.P1006= (on ENST00000520002; = p.P1005= on NM_033225.6) | Silent (SNP) | VAF 15/93 reads (16%) | called by muse, mutect2, varscan2
- CYP2W1 | c.1056C>T p.H352= | Silent (SNP) | VAF 36/96 reads (38%) | catalogued as rs761132341, COSV58269989; called by muse, mutect2, varscan2
- DYSF | c.2793C>T p.F931= | Silent (SNP) | VAF 29/60 reads (48%) | catalogued as rs146006518; ClinVar: likely benign; called by muse, mutect2, varscan2
- FOXJ2 | c.240C>T p.N80= | Silent (SNP) | VAF 12/223 reads (5%) | called by muse, mutect2
- IGHV3-21 | c.339T>C p.Y113= | Silent (SNP) | VAF 19/39 reads (49%) | called by muse, varscan2
- IRF2BP2 | c.1449A>G p.G483= | Silent (SNP) | VAF 50/169 reads (30%) | called by muse, mutect2, varscan2
- MAF | c.970C>T p.L324= | Silent (SNP) | VAF 104/204 reads (51%) | catalogued as rs774880014; called by muse, varscan2
- MAF | c.9A>C p.S3= | Silent (SNP) | VAF 23/60 reads (38%) | catalogued as COSV58153658; called by muse, mutect2, varscan2
- NOL12 | c.63C>T p.S21= | Silent (SNP) | VAF 128/248 reads (52%) | catalogued as rs1459228519; called by muse, mutect2, varscan2
- RSPH3 | c.315G>A p.S105= | Silent (SNP) | VAF 43/194 reads (22%) | catalogued as rs868494467; called by muse, mutect2, varscan2
- SCMH1 | c.1452C>T p.H484= (on ENST00000326197 / NM_001031694.2; = p.H437= on NM_012236.4) | Silent (SNP) | VAF 27/56 reads (48%) | catalogued as rs766824144; called by muse, mutect2, varscan2
- SEMA6B | c.159C>T p.P53= | Silent (SNP) | VAF 11/194 reads (6%) | called by muse, mutect2
- SLIT3 | c.3054C>T p.Y1018= | Silent (SNP) | VAF 54/116 reads (47%) | catalogued as rs766410120, COSV60596665; called by muse, mutect2, varscan2
- THSD7A | c.705G>A p.L235= | Silent (SNP) | VAF 166/263 reads (63%) | called by muse, mutect2, varscan2
- ZNF789 | c.249C>A p.S83= | Silent (SNP) | VAF 46/139 reads (33%) | catalogued as COSV58874726; called by muse, mutect2, varscan2
- AGAP1 | c.*2160G>A | 3'UTR (SNP) | VAF 23/38 reads (61%) | called by muse, mutect2, varscan2
- ARFGAP1 | c.*1651C>T | 3'UTR (SNP) | VAF 8/182 reads (4%) | called by muse, mutect2
- ARFGAP1 | c.*1652C>T | 3'UTR (SNP) | VAF 8/180 reads (4%) | catalogued as rs947262755; called by muse, mutect2
- ARHGEF10 | chr8:1958710 G>T | 3'Flank (SNP) | VAF 9/17 reads (53%) | catalogued as rs1052384875; called by muse, mutect2, varscan2
- BEST4 | c.*403G>A | 3'UTR (SNP) | VAF 26/67 reads (39%) | catalogued as rs1453711382; called by muse, mutect2, varscan2
- C12orf77 | n.251A>C | RNA (SNP) | VAF 45/88 reads (51%) | called by muse, mutect2, varscan2
- CDH11 | c.*953T>G | 3'UTR (SNP) | VAF 48/92 reads (52%) | called by muse, mutect2, varscan2
- CDKAL1 | c.286+9912C>A | Intron (SNP) | VAF 7/126 reads (6%) | called by muse, mutect2
- CFHR3 | c.613+812G>T | Intron (SNP) | VAF 23/53 reads (43%) | called by muse, mutect2, varscan2
- CICP28 | chr7:56811894 G>A | 3'Flank (SNP) | VAF 12/18 reads (67%) | called by mutect2, varscan2
- CLDN10 | c.*163_*166del | 3'UTR (DEL) | VAF 40/43 reads (93%) | catalogued as rs770460411; called by pindel, varscan2
- CRPPA | c.*16A>G | 3'UTR (SNP) | VAF 68/332 reads (20%) | called by muse, mutect2
- DAZL | c.*1166_*1169del | 3'UTR (DEL) | VAF 18/44 reads (41%) | called by mutect2, pindel, varscan2
- DGKB | c.*133C>G | 3'UTR (SNP) | VAF 161/247 reads (65%) | called by muse, mutect2, varscan2
- FAM174B | c.*691G>A | 3'UTR (SNP) | VAF 8/19 reads (42%) | catalogued as rs891703302; called by muse, mutect2, varscan2
- GLS | c.1650+2608T>C | Intron (SNP) | VAF 5/83 reads (6%) | called by muse, mutect2
- GRIN2C | c.399+33C>G | Intron (SNP) | VAF 18/254 reads (7%) | called by muse, mutect2
- GRIN2C | chr17:74860585 C>A | 5'Flank (SNP) | VAF 5/36 reads (14%) | called by muse, varscan2
- HINT3 | c.*1673A>G | 3'UTR (SNP) | VAF 8/67 reads (12%) | called by muse, mutect2
- IGHV3-21 | c.-29T>C | 5'UTR (SNP) | VAF 48/54 reads (89%) | catalogued as rs782172170; called by muse, mutect2, varscan2
- KCNMA1 | c.*411G>T | 3'UTR (SNP) | VAF 29/65 reads (45%) | called by muse, mutect2, varscan2
- MAF | c.-660T>G | 5'UTR (SNP) | VAF 26/71 reads (37%) | called by muse, varscan2
- NOVA1 | c.*157G>C | 3'UTR (SNP) | VAF 8/65 reads (12%) | called by muse, mutect2, varscan2
- OR13A1 | c.*537A>G | 3'UTR (SNP) | VAF 25/46 reads (54%) | called by muse, mutect2, varscan2
- OSBPL11 | c.*1345A>G | 3'UTR (SNP) | VAF 36/77 reads (47%) | catalogued as rs755569953; called by muse, mutect2, varscan2
- PAK6 | c.-5-968_-5-950del | Intron (DEL) | VAF 12/65 reads (18%) | called by mutect2, pindel, varscan2
- PHC1P1 | n.539G>A | RNA (SNP) | VAF 92/160 reads (58%) | called by muse, mutect2, varscan2
- RABL6 | c.810-43G>A | Intron (SNP) | VAF 40/79 reads (51%) | called by muse, mutect2, varscan2
- RHOJ | c.*411C>T | 3'UTR (SNP) | VAF 43/93 reads (46%) | called by muse, mutect2, varscan2
- RNF170 | c.*515C>A | 3'UTR (SNP) | VAF 30/61 reads (49%) | catalogued as rs1259313101; called by muse, mutect2, varscan2
- SETBP1 | c.*610C>A | 3'UTR (SNP) | VAF 28/84 reads (33%) | called by muse, mutect2, varscan2
- SFRP1 | c.*170C>T | 3'UTR (SNP) | VAF 35/65 reads (54%) | catalogued as rs1042972058; called by muse, mutect2, varscan2
- SH2B3 | c.*2232G>T | 3'UTR (SNP) | VAF 13/167 reads (8%) | called by muse, mutect2
- SORT1 | c.*1831G>A | 3'UTR (SNP) | VAF 7/50 reads (14%) | catalogued as rs985657684; called by muse, mutect2, varscan2
- SOX5 | c.*4335A>T | 3'UTR (SNP) | VAF 36/71 reads (51%) | called by muse, mutect2, varscan2
- STUM | c.*5898T>G | 3'UTR (SNP) | VAF 78/228 reads (34%) | called by muse, mutect2, varscan2
- TENM4 | c.*1516A>C | 3'UTR (SNP) | VAF 43/124 reads (35%) | called by muse, mutect2, varscan2
- TRPA1 | c.*61C>A | 3'UTR (SNP) | VAF 64/158 reads (41%) | called by muse, mutect2, varscan2
- UNKL | c.*1292A>C | 3'UTR (SNP) | VAF 37/89 reads (42%) | called by muse, mutect2, varscan2
- VEZT | c.*1404A>T | 3'UTR (SNP) | VAF 29/66 reads (44%) | called by muse, mutect2, varscan2
- WDR5 | c.*17C>G | 3'UTR (SNP) | VAF 16/264 reads (6%) | called by muse, mutect2
- ZYG11B | c.*3208C>A | 3'UTR (SNP) | VAF 32/68 reads (47%) | called by muse, mutect2, varscan2
